Somatic mutation profile of tumor specimen TCGA-66-2758-01A (aliquot TCGA-66-2758-01A-02W-0877-08) from TCGA case TCGA-66-2758, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.8 years (26,209 days).
Specimen TCGA-66-2758-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1b7302c-da70-4226-8d13-b5be666d4b87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2758-11A (Solid Tissue Normal), aliquot TCGA-66-2758-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e03617-1852-4159-9231-b63b3848ce1f

The open-access MAF lists 326 somatic variants for this specimen: 237 protein-altering or splice-affecting, 81 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 81, Nonsense Mutation 11, In Frame Del 7, Frame Shift Del 6, Intron 4, Splice Site 4, Frame Shift Ins 3, RNA 2, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 147/297 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520003, CM156966, COSV52780750, COSV52951418, COSV53606217; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.58102C>T p.R19368* (on ENST00000591111; = p.R11944* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 63/158 reads (40%) | catalogued as rs368452607, CM1514596, COSV60000901; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1554C>G p.Y518* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCC9 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as COSV53968887; called by muse, mutect2, varscan2
- ACOXL | c.1515G>C p.Q505H (on ENST00000389811 / NM_001371254.1; = p.Q475H on NM_001142807.4) | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV67735351; called by muse, mutect2, varscan2
- ACSL3 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as COSV62481797; called by muse, mutect2, varscan2
- ACVR1C | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54645613; called by muse, varscan2
- ADAM29 | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 116/687 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63662868; called by muse, mutect2, varscan2
- ADAMTS4 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63489766; called by muse, mutect2
- ADGRE1 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV51674749; called by muse, mutect2, varscan2
- AFAP1L1 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV57044863; called by muse, mutect2, varscan2
- AFMID | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 47/158 reads (30%) | catalogued as COSV59975842; called by muse, mutect2, varscan2
- AGXT2 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 58/612 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV51485707; called by muse, mutect2
- AKAP9 | c.9172T>C p.F3058L (on ENST00000359028; = p.F3034L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/605 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62343965; called by muse, mutect2, varscan2
- ANGPTL5 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57532720; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3500A>T p.Y1167F | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV51845400; called by muse, mutect2, varscan2
- ANKS1B | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61346988; called by muse, mutect2
- ANO4 | c.44T>A p.V15D | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV54593246; called by muse, mutect2, varscan2
- ARFGEF1 | c.2516A>G p.H839R | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51606873; called by muse, mutect2, varscan2
- ARHGAP36 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 116/196 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52265940; called by muse, mutect2, varscan2
- ARHGEF40 | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV53879745, COSV53885124; called by muse, mutect2, varscan2
- ARID5B | c.849G>A p.V283= | Splice Region (SNP) | VAF 13/31 reads (42%) | catalogued as COSV54418658; called by muse, mutect2, varscan2
- ASH2L | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV51699322, COSV99166927; called by muse, mutect2
- BCL9L | c.3937G>T p.V1313L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs760459717, COSV52683755; called by muse, mutect2, varscan2
- BDKRB1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV53705946; called by muse, mutect2, varscan2
- BIRC6 | c.7193C>A p.S2398Y | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70198332; called by muse, mutect2, varscan2
- BTBD16 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs184112208, COSV53262339; called by muse, mutect2, varscan2
- C1orf131 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59642193; called by muse, mutect2
- CACNA1S | c.5261G>C p.R1754T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV100755028, COSV62938793; called by muse, mutect2, varscan2
- CCDC9B | c.1523C>A p.T508K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs572485964, COSV66875213, COSV66875496; called by muse, mutect2, varscan2
- CCSER1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV61424321; called by muse, mutect2, varscan2
- CD1E | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as rs1394656791, COSV63769912, COSV63770792; called by muse, mutect2, varscan2
- CDH11 | c.1035G>C p.L345F | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.113); catalogued as COSV51759121; called by muse, mutect2, varscan2
- CFAP58 | c.2128G>C p.V710L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV100866073, COSV63833793; called by muse, mutect2, varscan2
- CFAP61 | c.1683T>A p.F561L | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55626686; called by muse, mutect2, varscan2
- CHERP | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.637); catalogued as COSV52223872; called by muse, mutect2, varscan2
- CLASP2 | c.3443A>G p.Y1148C (on ENST00000359576; = p.Y1147C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56280742; called by muse, mutect2, varscan2
- CMTR1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100990872; called by mutect2, varscan2
- CNGA1 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV62053981; called by mutect2, varscan2
- CNTN5 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs1209818461, COSV54303822; called by muse, mutect2, varscan2
- COL22A1 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 125/317 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV57333346; called by muse, mutect2, varscan2
- CPAMD8 | c.1771T>G p.S591A (on ENST00000651564; = p.S544A on NM_015692.5) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV52233515; called by muse, mutect2, varscan2
- CPZ | c.198G>T p.Q66H (on ENST00000360986 / NM_001014447.3; = p.Q55H on NM_003652.3) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV59922660; called by muse, mutect2, varscan2
- CR1 | c.6052C>G p.Q2018E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV65457614; called by muse, mutect2, varscan2
- CRNN | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 180/1788 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55121660; called by muse, mutect2
- CRTAP | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1185323876, COSV58013726; called by muse, mutect2, varscan2
- CSGALNACT1 | c.624T>A p.D208E | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV59976567; called by muse, mutect2, varscan2
- CSMD3 | c.7676G>C p.G2559A (on ENST00000297405 / NM_001363185.1; = p.G2455A on NM_052900.3) | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52158781, COSV99821688; called by muse, mutect2, varscan2
- CUX1 | c.3433+1G>T p.X1145_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV52897000; called by muse, mutect2, varscan2
- DCDC1 | c.4021G>A p.G1341R (on ENST00000597505 / NM_001367979.1; = p.G448R on NM_020869.3) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.31); catalogued as COSV100338087, COSV57998715; called by muse, mutect2, varscan2
- DDX56 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51835503; called by muse, mutect2, varscan2
- DEPTOR | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.585); catalogued as COSV53815003; called by muse, mutect2, varscan2
- DIAPH2 | c.3238C>G p.P1080A | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs1319243713, COSV61266542; called by muse, mutect2, varscan2
- DNAI1 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV54280472; called by muse, mutect2, varscan2
- DNAJC13 | c.4635G>T p.W1545C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53449295; called by muse, mutect2, varscan2
- DPP6 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV68056449; called by muse, mutect2, varscan2
- DRICH1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 89/450 reads (20%) | catalogued as COSV58503569; called by muse, mutect2, varscan2
- DYNLL2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV73897025; called by muse, mutect2, varscan2
- EIF2B5 | c.567G>A p.M189I (on ENST00000647909; = p.M181I on NM_003907.3) | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV56604337; called by muse, mutect2
- EIF4G1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59990424; called by muse, mutect2, varscan2
- EPHA10 | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs368330975, COSV57622095; called by muse, mutect2, varscan2
- FCER2 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs147413598, COSV60916234; called by muse, mutect2, varscan2
- FHOD3 | c.2894G>C p.R965T (on ENST00000359247 / NM_001281739.3; = p.R982T on NM_025135.5) | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57171320; called by muse, mutect2, varscan2
- FMO5 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54205806; called by muse, mutect2, varscan2
- FOXRED2 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV53399626; called by muse, mutect2, varscan2
- FUBP1 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53929633; called by muse, mutect2, varscan2
- FUT10 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59451060; called by muse, mutect2, varscan2
- G6PC2 | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV56371978; called by muse, mutect2, varscan2
- GABRA4 | c.1646A>T p.K549I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV51926285; called by muse, mutect2, varscan2
- GABRG1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1237024046, COSV54952913; called by mutect2, varscan2
- GEMIN8 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60550389; called by muse, mutect2, varscan2
- GOLGA6B | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV69770078; called by muse, mutect2, varscan2
- GON4L | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1008989857, COSV55192198; called by muse, mutect2, varscan2
- GPATCH8 | c.1651T>A p.W551R | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59194362; called by muse, mutect2, varscan2
- GPR174 | c.78C>G p.Y26* | Nonsense Mutation (SNP) | VAF 4/80 reads (5%) | catalogued as COSV52132151; called by muse, mutect2
- GRIK1 | c.2760G>C p.K920N (on ENST00000327783 / NM_001330994.2; = p.K876N on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); catalogued as COSV100583324, COSV59864820, COSV59870415; called by muse, mutect2, varscan2
- GRPR | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1226925757, COSV66669148, COSV66669197; called by muse, mutect2, varscan2
- H2AC17 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV58152477; called by muse, mutect2, varscan2
- HIGD1B | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 29/145 reads (20%) | catalogued as rs1160210617, COSV53655473; called by muse, mutect2, varscan2
- HYDIN | c.9320G>T p.G3107V | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59255190; called by muse, mutect2, varscan2
- ING3 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59950794; called by muse, mutect2, varscan2
- ISM2 | c.996G>C p.W332C (on ENST00000342219 / NM_199296.3; = p.G217A on NM_182509.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53634691; called by muse, mutect2, varscan2
- ITGB1 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV56480995; called by muse, mutect2
- ITPKC | c.1089C>G p.F363L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV54574293; called by muse, mutect2, varscan2
- KCNA1 | c.310A>T p.R104W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66837096; called by muse, mutect2, varscan2
- KIAA1191 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV53798789; called by muse, mutect2, varscan2
- KIFC2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV56760834; called by muse, mutect2, varscan2
- KRT14 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV51421062; called by muse, mutect2, varscan2
- KRT82 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57785847; called by muse, mutect2, varscan2
- LMOD1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66172496; called by muse, mutect2, varscan2
- LRP1B | c.10982G>T p.G3661V | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV67208450; called by muse, mutect2, varscan2
- LRP1B | c.10981G>C p.G3661R | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV67208454; called by muse, mutect2, varscan2
- LRP1B | c.9107C>A p.T3036K | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs757186045, COSV67208459; called by muse, mutect2, varscan2
- LTBP4 | c.3376G>A p.D1126N (on ENST00000308370 / NM_001042544.1; = p.D1089N on NM_003573.2) | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52580245, COSV52590948; called by muse, mutect2, varscan2
- LY75 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV55104644; called by muse, mutect2, varscan2
- LY75 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747989584, COSV55104653; called by muse, mutect2, varscan2
- MACF1 | c.14151C>G p.I4717M (on ENST00000372915; = p.I2650M on NM_012090.5) | Missense Mutation (SNP) | VAF 45/92 reads (49%) | catalogued as COSV57117979, COSV57133315; called by muse, mutect2, varscan2
- MASP1 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 151/783 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV61825805; called by muse, mutect2, varscan2
- MCM3AP | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV52438899; called by muse, mutect2, varscan2
- MED7 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV53850004; called by muse, mutect2, varscan2
- MEPCE | c.1612dup p.Q538Pfs*22 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | catalogued as rs752376043; called by pindel, varscan2
- MLH3 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1017281490, COSV53153789, COSV99469879; called by muse, mutect2, varscan2
- MLNR | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs574134980, COSV54531615; called by muse, mutect2, varscan2
- MMAA | c.1192A>C p.I398L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55579791; called by muse, mutect2, varscan2
- MRPL36 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56876456; called by muse, mutect2, varscan2
- MRPS31 | c.300A>C p.L100F | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV60266737; called by muse, mutect2, varscan2
- MS4A12 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV50014335; called by muse, mutect2, varscan2
- MYCBP2 | c.6973A>G p.M2325V (on ENST00000357337; = p.M2363V on NM_015057.5) | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1157762530, COSV62016110; called by muse, mutect2, varscan2
- MYH6 | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV62449618; called by muse, mutect2, varscan2
- MYPN | c.1577G>T p.S526I | Missense Mutation (SNP) | VAF 173/349 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62733254; called by muse, mutect2, varscan2
- MYT1L | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67717912; called by muse, mutect2, varscan2
- NEO1 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 44/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56070206; called by muse, varscan2
- NIN | c.1922A>T p.D641V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV55387747; called by muse, mutect2, varscan2
- NME8 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52249230; called by muse, mutect2, varscan2
- NOP14 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58625006; called by muse, mutect2, varscan2
- NOP56 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV61389690; called by muse, mutect2, varscan2
- OGDH | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as COSV56048658; called by muse, mutect2, varscan2
- OR2F2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 100/917 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68832720; called by muse, varscan2
- OR4A5 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60522291; called by muse, mutect2, varscan2
- OR5T1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 140/591 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57302516; called by muse, mutect2, varscan2
- P2RX4 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV61214203; called by muse, mutect2, varscan2
- PCDHB7 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50762881; called by muse, mutect2, varscan2
- PCDHB8 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50754678, COSV50762938; called by muse, mutect2, varscan2
- PCDHB8 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV50762943; called by muse, mutect2, varscan2
- PGLYRP4 | c.203G>C p.C68S | Missense Mutation (SNP) | VAF 311/875 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62835090; called by muse, mutect2, varscan2
- PHACTR1 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV60664753; called by muse, mutect2, varscan2
- PHF14 | c.1520A>G p.K507R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as COSV68855058; called by muse, mutect2, varscan2
- PHKG1 | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51916180; called by muse, mutect2, varscan2
- PHOX2B | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as COSV56929295; called by muse, mutect2, varscan2
- PKHD1L1 | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV65741623, COSV65753297; called by muse, mutect2, varscan2
- PLCB2 | c.1134G>C p.M378I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53032806; called by muse, mutect2, varscan2
- PLEKHA5 | c.2336G>C p.R779T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54698865; called by muse, mutect2, varscan2
- PNPLA5 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs374016542; called by muse, mutect2, varscan2
- PODXL2 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61065201; called by muse, mutect2, varscan2
- PRDM11 | c.1197G>A p.W399* (on ENST00000530656 / NM_001359633.1; = p.W365* on NM_001256695.1) | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55439337; called by muse, mutect2, varscan2
- PRKAR1A | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV62235478; called by muse, mutect2, varscan2
- PROM2 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs768628476, COSV58297690; called by muse, mutect2, varscan2
- PRRC2B | c.3925A>C p.K1309Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61936164; called by muse, mutect2, varscan2
- PSD4 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs761239222, COSV55525998; called by muse, mutect2, varscan2
- PSMD7 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV54697510; called by muse, mutect2, varscan2
- PXYLP1 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 123/972 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53890080; called by muse, mutect2, varscan2
- RAB11B | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs770759610, COSV60085635, COSV60085782; called by muse, mutect2, varscan2
- RARA | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54191606; called by muse, mutect2, varscan2
- RARS1 | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV51563081; called by muse, mutect2, varscan2
- RTL6 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.542); catalogued as COSV57979533, COSV57979730; called by muse, mutect2, varscan2
- RTN4 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58266764; called by muse, mutect2, varscan2
- RUBCN | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56365162; called by muse, mutect2, varscan2
- RXRG | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV63231949; called by muse, mutect2, varscan2
- RYR3 | c.12440C>A p.S4147Y (on ENST00000389232; = p.S4148Y on NM_001036.6) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV66785533; called by muse, mutect2, varscan2
- SCAF4 | c.1442G>T p.R481I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54586281; called by muse, mutect2, varscan2
- SEC24A | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV59746859; called by muse, mutect2, varscan2
- SEZ6 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as rs765736815, COSV57979118; called by muse, mutect2, varscan2
- SFTPA2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100958776; called by muse, mutect2, varscan2
- SH3PXD2B | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV61126307; called by muse, mutect2, varscan2
- SHROOM3 | c.4807A>T p.T1603S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56027672; called by muse, mutect2, varscan2
- SI | c.2236C>G p.L746V | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV52274794; called by muse, mutect2, varscan2
- SLC26A7 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 122/468 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52591361; called by muse, mutect2, varscan2
- SLC6A4 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55566498; called by muse, mutect2, varscan2
- SLC6A4 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.583); catalogued as COSV55566509; called by muse, mutect2, varscan2
- SLC9A5 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs769149966, COSV55361671; called by muse, mutect2, varscan2
- SLC9A9 | c.1893T>A p.Y631* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as rs1213323892, COSV57224941; called by muse, mutect2, varscan2
- SLCO1B1 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 64/628 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57009953, COSV57014552; called by muse, mutect2, varscan2
- SLITRK3 | c.2621C>G p.P874R | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.247); catalogued as COSV53847679; called by muse, mutect2, varscan2
- SLITRK5 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1377185185, COSV61521019; called by muse, mutect2, varscan2
- SNAPC4 | c.4388G>A p.R1463Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs201999899; called by muse, mutect2, varscan2
- SNRPB | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.267); catalogued as rs770650165, COSV60015122; called by muse, mutect2, varscan2
- SOWAHB | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554342; called by muse, mutect2, varscan2
- SPIRE1 | c.1288G>A p.G430S (on ENST00000409402 / NM_001128626.2; = p.G416S on NM_020148.3) | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100563936, COSV59155105; called by muse, mutect2
- SRGAP1 | c.2660C>G p.P887R | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV61896859; called by muse, mutect2, varscan2
- SRP54 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53739485; called by muse, mutect2, varscan2
- SS18 | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 116/722 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1259644070, COSV52260636; called by muse, mutect2, varscan2
- ST6GAL1 | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 33/427 reads (8%) | PolyPhen benign (0.014); catalogued as COSV51468828; called by muse, mutect2
- STARD8 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV52925132; called by mutect2, varscan2
- STC2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV54179370; called by muse, mutect2, varscan2
- STK3 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV69223083; called by muse, mutect2, varscan2
- STRIP2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746730562, COSV50803995; called by muse, mutect2, varscan2
- STRIP2 | c.2290_2292del p.E764del | In Frame Del (DEL) | VAF 41/106 reads (39%) | catalogued as rs760981516; called by pindel, varscan2
- SUN3 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV52048924, COSV52050022; called by muse, mutect2, varscan2
- TAL1 | c.480G>C p.M160I | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53746181; called by muse, mutect2, varscan2
- TBC1D25 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV65123565; called by muse, mutect2, varscan2
- TEP1 | c.1571T>A p.M524K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52991468; called by muse, mutect2
- TET3 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as COSV59880713; called by muse, mutect2, varscan2
- TEX15 | c.74G>T p.S25I (on ENST00000256246; = p.S408I on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56345274; called by muse, mutect2, varscan2
- THAP11 | c.746C>G p.S249W | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54645780; called by muse, mutect2, varscan2
- THAP12 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV52610313; called by muse, mutect2, varscan2
- TMCC3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451888005, COSV54153755; called by muse, mutect2, varscan2
- TMEM184B | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs866271142, COSV62672382; called by muse, mutect2, varscan2
- TMEM26 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as COSV53261864, COSV53263633; called by muse, mutect2, varscan2
- TMPRSS12 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68256187; called by mutect2, varscan2
- TNC | c.5691G>C p.E1897D | Missense Mutation (SNP) | VAF 77/466 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.208); catalogued as COSV60783865; called by muse, mutect2, varscan2
- TNC | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60783874; called by muse, mutect2
- TNR | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54881180; called by muse, mutect2, varscan2
- TNRC6B | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV57293743; called by muse, mutect2, varscan2
- TNS2 | c.439G>C p.A147P (on ENST00000314250 / NM_170754.4; = p.A157P on NM_015319.2) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552336137, COSV58576759; called by muse, mutect2, varscan2
- TPP1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV54997048; called by muse, mutect2, varscan2
- TRIM3 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs775716378, COSV61983681; called by muse, mutect2, varscan2
- TRIM5 | c.1481G>C p.*494Sext*50 | Nonstop Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as rs772811318, COSV59899527; called by muse, mutect2, varscan2
- TRIOBP | c.3155C>A p.P1052H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV60376453; called by muse, mutect2, varscan2
- TRIP10 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV57569693; called by muse, mutect2, varscan2
- TRMT1 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV52834457; called by muse, mutect2, varscan2
- TSGA10 | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61823003; called by muse, mutect2, varscan2
- TUT7 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1020835849, COSV52895245; called by muse, mutect2, varscan2
- USH2A | c.14090T>C p.F4697S | Missense Mutation (SNP) | VAF 178/512 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV56358929; called by muse, varscan2
- UTP20 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 307/897 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV55375720; called by muse, mutect2, varscan2
- VEPH1 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as COSV62877231, COSV62878218; called by muse, mutect2, varscan2
- VPS35L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV51981768; called by muse, mutect2, varscan2
- VPS39 | c.331G>A p.V111I (on ENST00000348544 / NM_001301138.2; = p.V100I on NM_015289.5) | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58789035; called by muse, mutect2, varscan2
- WDR17 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV54572370, COSV99706644; called by muse, mutect2, varscan2
- ZC3H18 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV56324181, COSV56328040; called by muse, mutect2, varscan2
- ZHX2 | c.866A>T p.Q289L | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100072448, COSV58712457; called by muse, mutect2, varscan2
- ZNF254 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV61641995; called by muse, mutect2, varscan2
- ZNF266 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV63221970, COSV63223384; called by muse, mutect2, varscan2
- ZNF573 | c.1401G>C p.K467N (on ENST00000536220 / NM_001172692.1; = p.K409N on NM_152360.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59824945; called by muse, mutect2, varscan2
- ZNF77 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 195/351 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.514); catalogued as COSV58821726; called by muse, mutect2, varscan2
- ZNFX1 | c.5203G>C p.E1735Q | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs559641061, COSV65596484; called by muse, mutect2, varscan2
- ZWILCH | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV57179411; called by muse, mutect2, varscan2
- ZZZ3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 120/554 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.186); catalogued as rs1381445786, COSV66232339; called by muse, mutect2, varscan2
- AGTPBP1 | c.1048_1059del p.T350_V353del (on ENST00000357081 / NM_001330701.2; = p.T310_V313del on NM_015239.2) | In Frame Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, varscan2
- ARHGEF2 | c.2013del p.P672Qfs*7 (on ENST00000361247 / NM_001162383.2; = p.P644Qfs*7 on NM_004723.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- C9orf131 | c.2007_2018del p.D670_A673del | In Frame Del (DEL) | VAF 18/169 reads (11%) | called by mutect2, pindel
- CYP24A1 | c.1061del p.K354Rfs*18 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- DENND2B | c.2455_2456del p.R819Wfs*38 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- DHX15 | c.2060_2071del p.I687_R690del | In Frame Del (DEL) | VAF 71/124 reads (57%) | called by mutect2, pindel, varscan2
- FXR2 | c.301-1_302delinsTTTTA p.X101_splice | Splice Site (INS) | VAF 13/82 reads (16%) | called by pindel, varscan2*
- IGKV1-9 | c.261T>A p.S87R | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- LAMA3 | c.2308_2318del p.X770_splice | Splice Site (DEL) | VAF 22/190 reads (12%) | called by mutect2, pindel
- LILRB3 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.917); called by muse, mutect2
- NFAT5 | c.3182dup p.L1061Ffs*35 | Frame Shift Ins (INS) | VAF 115/560 reads (21%) | called by mutect2, pindel, varscan2
- NFAT5 | c.4481_4501del p.Q1494_P1500del | In Frame Del (DEL) | VAF 92/359 reads (26%) | called by mutect2, pindel, varscan2
- ORAI1 | c.493dup p.H165Pfs*2 | Frame Shift Ins (INS) | VAF 36/131 reads (27%) | called by mutect2, pindel, varscan2
- RAB21 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- SERPINB11 | c.862del p.R288Dfs*10 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, varscan2
- SMPD4 | c.1497del p.K500Sfs*21 (on ENST00000409031 / NM_017951.4; = p.K471Sfs*21 on NM_017751.4) | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- UFL1 | c.1041_1049del p.R347_F349del | In Frame Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- ZBED4 | c.3287_3289delinsT p.H1096Lfs*3 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by pindel, varscan2*
- ZNF521 | c.688_717del p.G230_D239del | In Frame Del (DEL) | VAF 52/333 reads (16%) | called by mutect2, pindel
- ACVR1C | c.582G>T p.T194= | Silent (SNP) | VAF 59/279 reads (21%) | catalogued as COSV54645623, COSV99694642; called by muse, varscan2
- ADCY10 | c.1272T>A p.I424= | Silent (SNP) | VAF 104/321 reads (32%) | catalogued as COSV63240121; called by muse, mutect2, varscan2
- ALDH3B1 | c.411G>A p.L137= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1169794909, COSV50287838; called by muse, mutect2, varscan2
- AP3B1 | c.2778A>T p.I926= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54882002; called by muse, mutect2, varscan2
- ATP2B3 | c.2475C>T p.I825= | Silent (SNP) | VAF 131/201 reads (65%) | catalogued as COSV54845027; called by muse, mutect2, varscan2
- B4GALT1 | c.483G>C p.V161= | Silent (SNP) | VAF 43/255 reads (17%) | catalogued as COSV65707918; called by muse, mutect2, varscan2
- CACNB3 | c.1413G>A p.R471= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV56397924; called by muse, mutect2, varscan2
- CASP7 | c.564G>C p.G188= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as COSV61881596; called by muse, mutect2, varscan2
- CD34 | c.114T>A p.T38= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV60412627; called by muse, mutect2, varscan2
- CILP | c.1626G>T p.V542= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV56023439; called by muse, mutect2, varscan2
- CYP4F2 | c.768C>T p.F256= | Silent (SNP) | VAF 114/896 reads (13%) | catalogued as COSV50000937; called by muse, mutect2, varscan2
- DGUOK | c.111G>T p.G37= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV51203504; called by muse, mutect2, varscan2
- DNAH12 | c.837T>G p.G279= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV60856612; called by muse, mutect2, varscan2
- DNAJC27 | c.699C>G p.V233= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV53094928; called by muse, mutect2, varscan2
- FAAH2 | c.48G>C p.A16= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV66507024; called by muse, mutect2, varscan2
- GAB1 | c.2079G>C p.V693= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53756014; called by muse, mutect2, varscan2
- GABRG2 | c.1377C>T p.C459= (on ENST00000361925 / NM_001375343.1; = p.C419= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as COSV62717379; called by muse, mutect2, varscan2
- GBF1 | c.5148A>G p.E1716= (on ENST00000369983 / NM_001377137.1; = p.E1715= on NM_004193.3) | Silent (SNP) | VAF 82/474 reads (17%) | catalogued as COSV64142489; called by muse, mutect2, varscan2
- GJC1 | c.99C>T p.I33= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs1293553169, COSV57911072; called by muse, mutect2, varscan2
- GPR182 | c.1023G>A p.K341= | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as COSV55626001; called by muse, mutect2, varscan2
- GTF3C4 | c.819T>C p.S273= | Silent (SNP) | VAF 139/215 reads (65%) | catalogued as COSV64645236; called by muse, mutect2, varscan2
- H2AZ2 | c.363G>A p.K121= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV56062298; called by muse, mutect2, varscan2
- HLCS | c.588T>A p.I196= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV60792818; called by muse, mutect2, varscan2
- IL19 | c.159C>T p.T53= | Silent (SNP) | VAF 99/363 reads (27%) | catalogued as COSV54283319; called by muse, mutect2, varscan2
- IRF4 | c.804G>A p.T268= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs769596072, COSV66704996; called by muse, mutect2, varscan2
- IVD | c.759C>A p.T253= (on ENST00000651168; = p.T250= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV51099014; called by muse, mutect2, varscan2
- KRTAP5-6 | c.213C>A p.G71= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV66289186; called by muse, mutect2, varscan2
- L1CAM | c.2106G>T p.P702= | Silent (SNP) | VAF 44/50 reads (88%) | catalogued as COSV62827812; called by muse, mutect2, varscan2
- LARP7 | c.1092A>G p.K364= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV60520719; called by muse, mutect2, varscan2
- MAP3K5 | c.1314C>G p.L438= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV62888749; called by muse, mutect2, varscan2
- MORC1 | c.684G>A p.L228= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as COSV51718397; called by muse, mutect2, varscan2
- MTUS1 | c.1821C>G p.A607= | Silent (SNP) | VAF 53/291 reads (18%) | catalogued as rs375815032, COSV50550554, COSV50554803; called by muse, mutect2, varscan2
- MUC16 | c.18783G>A p.K6261= | Silent (SNP) | VAF 74/334 reads (22%) | catalogued as COSV67461226; called by muse, mutect2, varscan2
- MUC4 | c.14883G>A p.V4961= (on ENST00000463781 / NM_018406.7; = p.V725= on NM_004532.6) | Silent (SNP) | VAF 44/466 reads (9%) | catalogued as COSV57777391; called by muse, mutect2
- NAV1 | c.3114G>A p.E1038= | Silent (SNP) | VAF 102/490 reads (21%) | catalogued as COSV55216726; called by muse, mutect2, varscan2
- NCOA1 | c.2304G>T p.L768= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV56042571; called by muse, mutect2, varscan2
- NLRC3 | c.2910G>A p.L970= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs780123823, COSV57089875; called by mutect2, varscan2
- OBSL1 | c.912C>G p.L304= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54717485; called by mutect2, varscan2
- OR2F2 | c.222C>A p.A74= | Silent (SNP) | VAF 102/915 reads (11%) | catalogued as COSV101283808, COSV68832726; called by muse, varscan2
- OR52A5 | c.492C>A p.L164= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV56614944; called by muse, mutect2, varscan2
- OR52J3 | c.840C>A p.L280= | Silent (SNP) | VAF 65/305 reads (21%) | catalogued as COSV66746798; called by muse, mutect2, varscan2
- PCDHA8 | c.223C>T p.L75= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV65336278; called by muse, mutect2, varscan2
- PCDHB7 | c.1893C>T p.S631= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as rs781839893, COSV50762936; called by muse, mutect2, varscan2
- PCDHGC4 | c.831C>T p.V277= | Silent (SNP) | VAF 43/195 reads (22%) | catalogued as COSV52749638; called by muse, mutect2, varscan2
- PGLYRP4 | c.204C>T p.C68= | Silent (SNP) | VAF 309/866 reads (36%) | catalogued as COSV62835083; called by muse, mutect2, varscan2
- PIWIL1 | c.477G>A p.K159= | Silent (SNP) | VAF 71/142 reads (50%) | catalogued as COSV55346013; called by muse, mutect2, varscan2
- POLR3GL | c.108G>A p.Q36= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65215379; called by muse, mutect2, varscan2
- PPM1E | c.1320C>A p.T440= | Silent (SNP) | VAF 78/218 reads (36%) | catalogued as rs151205066, COSV57573188; called by muse, mutect2, varscan2
- PRAM1 | c.651G>A p.A217= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs900018925, COSV55313216; called by muse, mutect2, varscan2
- PRX | c.507C>T p.G169= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV52529451, COSV52534446; called by muse, mutect2, varscan2
- PSME3IP1 | c.729C>A p.S243= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV58429036; called by muse, mutect2, varscan2
- PTPRM | c.1785A>T p.T595= | Silent (SNP) | VAF 38/416 reads (9%) | catalogued as COSV59854997; called by muse, mutect2
- RAP2A | c.123C>T p.R41= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV55354868; called by muse, mutect2, varscan2
- RELT | c.843C>G p.L281= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV50361234; called by muse, mutect2, varscan2
- RMND5B | c.730C>A p.R244= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV51070937, COSV51070938; called by muse, mutect2
- RP1 | c.2532T>A p.S844= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV55115091; called by muse, mutect2, varscan2
- RPL3 | c.1113C>T p.T371= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs376619725, COSV53365148; called by muse, mutect2, varscan2
- SEPTIN10 | c.825C>G p.V275= | Silent (SNP) | VAF 41/327 reads (13%) | catalogued as COSV61780014; called by muse, mutect2, varscan2
- SHISA2 | c.399C>A p.S133= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV60110598; called by muse, mutect2, varscan2
- SIT1 | c.267G>A p.L89= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1169261703, COSV52399821; called by muse, mutect2, varscan2
- SLC26A7 | c.1722G>T p.L574= | Silent (SNP) | VAF 124/473 reads (26%) | catalogued as COSV52591342; called by muse, mutect2, varscan2
- SLC30A3 | c.678C>A p.P226= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV51985061; called by muse, mutect2, varscan2
- SLC45A3 | c.498C>T p.F166= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV65654847; called by muse, mutect2
- SLC6A3 | c.615C>T p.N205= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as rs764540812, COSV54362848; ClinVar: likely benign; called by muse, mutect2
- SLC9C2 | c.2943C>G p.G981= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV62945318; called by muse, mutect2, varscan2
- SPATA31D1 | c.3252T>C p.D1084= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV61194966; called by muse, mutect2, varscan2
- SPEN | c.3699C>A p.V1233= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV65360830; called by muse, mutect2, varscan2
- TET2 | c.324G>A p.Q108= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV54407515; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1371C>G p.V457= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as COSV62625937; called by muse, varscan2
- TSPY2 | c.90G>C p.V30= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100289189; called by muse, mutect2, varscan2
- TTN | c.2520C>A p.A840= (on ENST00000591111; = p.A794= on NM_003319.4) | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV60000999; called by muse, mutect2, varscan2
- TUBD1 | c.705G>A p.L235= | Silent (SNP) | VAF 81/235 reads (34%) | catalogued as COSV57872631; called by muse, mutect2, varscan2
- WDR46 | c.1027T>C p.L343= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV65842199; called by muse, mutect2, varscan2
- WWTR1 | c.132G>T p.R44= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV62291114; called by muse, mutect2, varscan2
- XIRP2 | c.9255G>A p.E3085= (on ENST00000628543; = p.E3260= on NM_152381.6) | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as rs746756891, COSV54695003, COSV99744299; called by muse, mutect2, varscan2
- XXYLT1 | c.777A>T p.P259= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as COSV59983102; called by muse, mutect2, varscan2
- ZC3H4 | c.3432C>T p.S1144= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs780922122, COSV53412152; called by muse, mutect2, varscan2
- ZFPM2 | c.672G>T p.L224= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV65873195, COSV65873395; called by muse, mutect2, varscan2
- ZFPM2 | c.1428C>T p.S476= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV65873201; called by muse, mutect2, varscan2
- ZNF112 | c.639C>A p.V213= (on ENST00000337401 / NM_001083335.2; = p.V207= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as COSV61619740; called by muse, mutect2, varscan2
- ZNF491 | c.408T>C p.C136= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as COSV60057191; called by muse, mutect2, varscan2
- ARL6IP6 | c.-1C>G | 5'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100424001; called by mutect2, varscan2
- C12orf76 | n.674G>A | RNA (SNP) | VAF 22/86 reads (26%) | catalogued as COSV55676052; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445783 G>T | 3'Flank (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4346A>C | Intron (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100026109; called by muse, mutect2, varscan2
- PDE7A | c.139-6056A>T | Intron (SNP) | VAF 43/213 reads (20%) | catalogued as COSV101052661; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23878T>A | Intron (SNP) | VAF 40/145 reads (28%) | catalogued as COSV67442969; called by muse, mutect2, varscan2
- SNORD116-26 | n.72G>T | RNA (SNP) | VAF 53/304 reads (17%) | called by muse, mutect2, varscan2
- TSR1 | c.1770+147G>C | Intron (SNP) | VAF 20/78 reads (26%) | catalogued as rs751793771, COSV100027008; called by muse, mutect2, varscan2
